Somatic mutation profile of tumor specimen MBCProject_0004_T2_WES (aliquot MBCProject_0004_T2_WES_1) from CMI case MBCProject_0004, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 58.2 years (21,242 days).
Specimen MBCProject_0004_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92cdccaa-1bd3-499d-9d77-fd1696096f58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0004_SALIVA (Saliva), aliquot MBCProject_0004_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c12f1f62-1862-4beb-8390-a53ee2603d25

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Intron 2, Splice Site 2, 3'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.531+1G>A p.X177_splice | Splice Site (SNP) | VAF 14/116 reads (12%) | hotspot (GDC flag); catalogued as rs1131690808, COSV55728459; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD15 | c.47_55del p.A16_L18del | In Frame Del (DEL) | VAF 16/150 reads (11%) | catalogued as rs769564086; called by mutect2, pindel
- ASXL1 | c.3274G>T p.V1092L | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV60102471; called by muse, mutect2, varscan2
- COQ8A | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 31/552 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1179795268, COSV100825585, COSV100825628; called by muse, mutect2
- CTSK | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 24/345 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs747914097, CM166936, COSV55011355; ClinVar: uncertain significance; called by muse, mutect2
- DCBLD1 | c.1924G>A p.V642I | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1021792486, COSV99757670; called by muse, mutect2
- ERBB2 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 51/277 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as COSV54067264; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HELLS | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs1308854161, COSV53294641; called by muse, mutect2
- KMT2C | c.13320T>G p.Y4440* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV51447456; called by muse, mutect2, varscan2
- MAN1B1 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV65378758; called by muse, mutect2
- MAPK8IP1 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 25/282 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs768339614, COSV99571588; called by muse, mutect2
- NEFH | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs186355000; called by muse, mutect2, varscan2
- RESF1 | c.4775G>A p.R1592H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs974575885, COSV57021198; called by muse, mutect2
- GSE1 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PRRC2B | c.6514G>T p.A2172S | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RIPK1 | c.456_459+9del p.X152_splice | Splice Site (DEL) | VAF 12/82 reads (15%) | called by mutect2, pindel
- TACC2 | c.4977A>T p.E1659D | Missense Mutation (SNP) | VAF 51/277 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TBX3 | c.347_348insA p.F116Lfs*22 | Frame Shift Ins (INS) | VAF 34/240 reads (14%) | called by pindel, varscan2
- ARID2 | c.5070C>T p.H1690= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs1262038394; called by muse, mutect2, varscan2
- NUDT16L1 | c.147G>C p.S49= | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as rs371654760; called by muse, mutect2, varscan2
- OR2B11 | c.357G>A p.L119= | Silent (SNP) | VAF 35/151 reads (23%) | called by muse, mutect2, varscan2
- VOPP1 | c.225C>T p.C75= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs776114643; called by muse, mutect2, varscan2
- CACNB4 | c.148-90287C>T | Intron (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- FMR1 | c.-10T>G | 5'UTR (SNP) | VAF 52/307 reads (17%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.751C>T | RNA (SNP) | VAF 11/46 reads (24%) | catalogued as rs776750375; called by muse, mutect2, varscan2
- KCNC4 | c.*546A>T | 3'UTR (SNP) | VAF 14/281 reads (5%) | called by muse, mutect2
- REEP6 | c.348+34C>T | Intron (SNP) | VAF 6/44 reads (14%) | catalogued as rs1253335446; called by muse, mutect2
